OHSU case 1864 — OHSU-CNL: Philadelphia-Negative Neutrophilic Leukemias (CNL/aCML/MDS/MPNu)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Chronic Myeloproliferative Disorders; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/485e884a-374e-4813-b5f9-2c5f747758fd

Biospecimens (1 sample)
- Sample 2383R: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Fresh.
